Somatic mutation profile of tumor specimen TCGA-K7-A5RG-01A (aliquot TCGA-K7-A5RG-01A-11D-A28X-10) from TCGA case TCGA-K7-A5RG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.3 years (24,218 days).
Specimen TCGA-K7-A5RG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a8825cb-5685-4ab7-8a66-d6227951e41b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K7-A5RG-10A (Blood Derived Normal), aliquot TCGA-K7-A5RG-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/994e9c50-9ac9-42c5-8274-a1efa1be200e

The open-access MAF lists 131 somatic variants for this specimen: 102 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 27, Nonsense Mutation 7, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, Nonstop Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 35/177 reads (20%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1909A>G p.T637A | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52709561; called by muse, mutect2, varscan2
- ABCA4 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761112891, COSV64670659, COSV64676764; called by muse, mutect2, varscan2
- ACAD11 | c.1720A>G p.M574V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1039377839, COSV53900398; called by muse, mutect2, varscan2
- ADGRE2 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59695781; called by muse, mutect2, varscan2
- ALX4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368050443; called by muse, mutect2, varscan2
- AMER1 | c.959A>T p.K320I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57665882; called by muse, mutect2
- ASAP2 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55637143; called by muse, mutect2
- ATP1B3 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.406); catalogued as COSV53951255; called by muse, mutect2, varscan2
- ATP4A | c.1523A>T p.D508V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV52871018; called by muse, mutect2, varscan2
- BMP7 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV101216059; called by muse, mutect2
- C17orf49 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.975); catalogued as rs768995542, COSV66081225; called by muse, mutect2, varscan2
- C1QA | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV65890005; called by muse, mutect2, varscan2
- CACNA1H | c.2420C>T p.T807M | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773952204, COSV61986525; called by muse, mutect2, varscan2
- CCT3 | c.254G>C p.R85P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55290883; called by mutect2, varscan2
- CD209 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.093); catalogued as rs752457226, COSV52657534; called by muse, mutect2, varscan2
- CDYL | c.679C>A p.Q227K (on ENST00000328908 / NM_001368125.1; = p.Q173K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV59361336; called by muse, mutect2, varscan2
- CFAP251 | c.1911C>A p.N637K | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56614646; called by muse, mutect2
- CHRM3 | c.1018A>G p.N340D | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.099); catalogued as COSV55099489; called by muse, mutect2, varscan2
- DAO | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV57324098; called by muse, mutect2
- DCHS1 | c.9796C>T p.P3266S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54999445; called by muse, mutect2, varscan2
- DCTN2 | c.261G>T p.E87D (on ENST00000548249 / NM_001261413.2; = p.E92D on NM_006400.4) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV71553302; called by muse, mutect2, varscan2
- DDX18 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1417732613, COSV54308622; called by muse, mutect2
- DNAH10 | c.10898A>G p.E3633G (on ENST00000409039; = p.E3572G on NM_207437.3) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68999523; called by muse, mutect2, varscan2
- DPPA2 | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV72118275; called by muse, mutect2, varscan2
- EFNA3 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV63625919; called by muse, mutect2, varscan2
- EHD2 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54410399; called by muse, mutect2
- ERC2 | c.488T>A p.L163H | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV55654455; called by muse, mutect2, varscan2
- EXT2 | c.1870A>G p.M624V (on ENST00000343631; = p.M657V on NM_000401.3) | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs772217310, COSV59153939; called by muse, mutect2, varscan2
- EYA1 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58156391, COSV58171428; called by muse, mutect2, varscan2
- FBXO24 | c.878A>G p.K293R (on ENST00000241071 / NM_033506.3; = p.K331R on NM_012172.5) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); catalogued as COSV53828812; called by muse, mutect2, varscan2
- FSIP1 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV63226468; called by muse, mutect2
- GAPVD1 | c.4021G>A p.D1341N (on ENST00000394104; = p.D1350N on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52926521; called by muse, mutect2, varscan2
- GLYATL2 | c.769T>G p.Y257D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54851096; called by mutect2, varscan2
- GUCY1B1 | c.102A>T p.E34D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV52378209; called by muse, mutect2, varscan2
- GUCY1B1 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV52378218; called by muse, mutect2, varscan2
- HACL1 | c.1072A>T p.K358* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV58256162; called by muse, mutect2, varscan2
- HHAT | c.1405A>T p.T469S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV54807039; called by muse, mutect2, varscan2
- HOXB7 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); catalogued as COSV53311343, COSV99494190; called by muse, mutect2, varscan2
- HTT | c.4458G>T p.Q1486H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV61867624; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.164); catalogued as COSV56291252; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1238A>G p.Q413R | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as COSV61164006; called by muse, mutect2, varscan2
- ITGB1 | c.544A>C p.I182L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56485916; called by muse, mutect2
- ITPRIPL1 | c.229A>G p.T77A (on ENST00000439118 / NM_001008949.3; = p.T85A on NM_178495.6) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63153468, COSV63154416; called by muse, mutect2, varscan2
- JUN | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64664829; called by muse, mutect2
- KCNC2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV54369344; called by muse, mutect2
- KEAP1 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50633034, COSV50634632; called by muse, mutect2, varscan2
- KIF6 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54670091; called by muse, mutect2, varscan2
- LDB3 | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV53947827; called by muse, mutect2
- LHFPL3 | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV67815253; called by muse, mutect2, varscan2
- LRFN2 | c.1661T>C p.M554T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57833019; called by muse, mutect2, varscan2
- LRFN5 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53270016; called by muse, mutect2, varscan2
- MEFV | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV54826154; called by muse, mutect2, varscan2
- MICU3 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV58848262; called by muse, mutect2, varscan2
- MSH5 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.11); catalogued as COSV65211061; called by muse, mutect2, varscan2
- MUC16 | c.14080C>T p.L4694F | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as COSV67486278; called by muse, mutect2, varscan2
- NAV3 | c.2518T>C p.Y840H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV57105303; called by mutect2, varscan2
- NDUFAF7 | c.1088T>C p.M363T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs758326561, COSV50018559; called by muse, mutect2, varscan2
- NFKBID | c.397G>A p.V133I (on ENST00000396901; = p.V285I on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as rs1374673489, COSV61729718; called by muse, mutect2
- NOL8 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV62637172; called by muse, mutect2
- NR1H3 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV68008755; called by muse, mutect2, varscan2
- OR6C4 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 6/85 reads (7%) | catalogued as COSV67793221; called by muse, mutect2
- PCDHA2 | c.998A>T p.H333L | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV65370292; called by muse, mutect2, varscan2
- PCK1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100099923, COSV60130391, COSV60131004; called by muse, mutect2, varscan2
- PHKG2 | c.67A>T p.K23* | Nonsense Mutation (SNP) | VAF 30/195 reads (15%) | catalogued as COSV60313409; called by muse, mutect2, varscan2
- PIK3R2 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 28/204 reads (14%) | catalogued as COSV55849820; called by muse, mutect2, varscan2
- PLA2G4A | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV66556176; called by muse, varscan2
- PLEKHG7 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV67338140; called by muse, mutect2, varscan2
- PODXL | c.381A>C p.K127N | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs767012209, COSV59872353; called by muse, mutect2, varscan2
- PSMC1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV54321861; called by muse, mutect2, varscan2
- PSMD1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58082447; called by muse, mutect2
- PXDNL | c.1526C>G p.A509G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV62496309; called by muse, mutect2, varscan2
- RAI14 | c.1775A>C p.K592T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs1174338142, COSV54301608; called by muse, mutect2, varscan2
- RANGAP1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs567605253, COSV62364451; called by muse, mutect2, varscan2
- RBBP5 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV52706332; called by muse, mutect2, varscan2
- RBPJ | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV60755471, COSV60758195; called by muse, mutect2, varscan2
- SAMD9 | c.4241A>G p.Q1414R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.109); catalogued as COSV66075321, COSV66077164; called by muse, mutect2, varscan2
- SCRIB | c.1498C>G p.P500A | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs759838353, COSV57592184; called by muse, mutect2, varscan2
- SDK2 | c.6316G>A p.D2106N | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs199923333, COSV66194052; called by muse, mutect2
- SIAH2 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV57262809; called by muse, mutect2, varscan2
- SLC43A2 | c.1439A>T p.Q480L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV56770794; called by mutect2, varscan2
- SLC9A9 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 63/407 reads (15%) | catalogued as COSV57241472; called by muse, mutect2, varscan2
- SLITRK5 | c.822C>A p.D274E | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61525392; called by muse, mutect2, varscan2
- SOCS5 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60603916, COSV60604974; called by muse, mutect2, varscan2
- SPOCK3 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV62734132; called by mutect2, varscan2
- TBC1D5 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53767695; called by muse, mutect2, varscan2
- TCF12 | c.70A>G p.S24G | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV51018473; called by muse, mutect2, varscan2
- TENT2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57138968; called by muse, mutect2, varscan2
- TLX3 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 37/297 reads (12%) | catalogued as COSV51541598; called by muse, mutect2, varscan2
- TMEM14C | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs1282771288, COSV57639120; called by muse, mutect2, varscan2
- TNFRSF21 | c.1188A>T p.K396N | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57284535; called by muse, mutect2, varscan2
- TSPAN31 | c.633A>G p.*211Wext*6 | Nonstop Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV57276918; called by muse, mutect2
- VEPH1 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100747710; called by muse, mutect2, varscan2
- WNT1 | c.670T>C p.S224P | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53296651; called by muse, mutect2, varscan2
- YLPM1 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.164); catalogued as rs376895690; called by muse, mutect2, varscan2
- ZBTB18 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.935); catalogued as rs769296405, COSV62398239; called by muse, mutect2, varscan2
- ZNF445 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV68539488; called by muse, mutect2
- ZNF536 | c.3740G>T p.G1247V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as COSV62831954; called by muse, mutect2, varscan2
- ZNF592 | c.1541G>C p.S514T | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55438967; called by muse, mutect2
- ZNF790 | c.1019G>C p.C340S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375770964; called by muse, mutect2, varscan2
- ADH5 | c.236dup p.V80Sfs*3 | Frame Shift Ins (INS) | VAF 26/188 reads (14%) | called by mutect2, pindel, varscan2
- MUC20 | c.1502_1505del p.P501Lfs*9 | Frame Shift Del (DEL) | VAF 45/394 reads (11%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.6036T>A p.S2012= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV54964391; called by muse, mutect2, varscan2
- AGAP2 | c.3045G>C p.T1015= (on ENST00000547588 / NM_001122772.2; = p.T659= on NM_014770.4) | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV57730883; called by muse, mutect2, varscan2
- ANKRD26 | c.1110A>G p.K370= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV65797837; called by muse, mutect2, varscan2
- ASTN1 | c.3177C>A p.L1059= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV62493780, COSV62503855; called by muse, mutect2, varscan2
- DNAH3 | c.8376A>G p.P2792= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV54544467; called by muse, mutect2, varscan2
- EFCAB12 | c.15T>C p.Y5= | Silent (SNP) | VAF 34/246 reads (14%) | catalogued as COSV51445604; called by muse, mutect2, varscan2
- ESRP1 | c.648C>T p.S216= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV64412029; called by muse, mutect2, varscan2
- HTR1A | c.846G>A p.R282= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV60502491; called by muse, mutect2, varscan2
- IGF2BP1 | c.1062T>C p.D354= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as COSV51734915; called by muse, varscan2
- IGFN1 | c.1806G>T p.G602= (on ENST00000295591 / NM_001367841.1; = p.G3059= on NM_001164586.2) | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as COSV55181863; called by muse, mutect2, varscan2
- ILDR1 | c.1002A>T p.P334= (on ENST00000344209 / NM_001199799.2; = p.P290= on NM_175924.4) | Silent (SNP) | VAF 19/184 reads (10%) | catalogued as COSV56552935; called by muse, mutect2, varscan2
- JAG1 | c.429T>C p.N143= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as COSV54761629; called by muse, mutect2, varscan2
- KIAA1191 | c.909T>A p.T303= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53799789; called by muse, mutect2
- KIAA1549 | c.4293T>C p.D1431= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV54324793; called by muse, mutect2
- MUC7 | c.186C>T p.S62= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV59219841, COSV59220383; called by muse, mutect2
- OR6C68 | c.780A>G p.P260= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV65563777; called by muse, mutect2, varscan2
- OSCAR | c.147T>A p.P49= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV52928379; called by muse, mutect2, varscan2
- PCDH15 | c.5703T>C p.S1901= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1265145868, COSV57265987, COSV57375072; called by muse, mutect2, varscan2
- PLAAT3 | c.93A>G p.G31= | Silent (SNP) | VAF 42/255 reads (16%) | catalogued as COSV60312525; called by muse, mutect2, varscan2
- PTPRT | c.1752C>A p.T584= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV61994931; called by muse, mutect2
- SH3GL2 | c.591T>A p.A197= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV66054102; called by muse, mutect2, varscan2
- SLC12A3 | c.2019C>A p.I673= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs758071801, COSV52638056; called by mutect2, varscan2
- SLC9A3 | c.1494C>T p.I498= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs200474984; called by muse, mutect2, varscan2
- STARD6 | c.549A>C p.I183= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV57143326; called by muse, mutect2
- TTN | c.67338G>A p.L22446= (on ENST00000591111; = p.L15022= on NM_003319.4) | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV60277512; called by muse, mutect2, varscan2
- VEPH1 | c.288C>A p.P96= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV100747711; called by muse, mutect2, varscan2
- ZNF546 | c.1194A>T p.S398= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV61259199; called by muse, mutect2, varscan2
- AC244258.1 | n.654T>G | RNA (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- Z82195.2 | n.416-19599C>T | Intron (SNP) | VAF 50/168 reads (30%) | catalogued as rs1296376409; called by muse, mutect2, varscan2
